Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A8ZZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A8ZZ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

* Consult Report *

FINAL

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: F
DOB: [REDACTED] Age: [REDACTED]

Service: [REDACTED]
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Accessioned: [REDACTED]
Reported: [REDACTED]

Physician(s): [REDACTED] M.D.

DIAGNOSIS

UTERUS, ENDOCERVIX, CURETTAGE

- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED

UTERUS, CERVIX, LEEP CONIZATION

- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, KERATINIZING (SEE COMMENT)

- RESECTION MARGINS ARE EXTENSIVELY INVOLVED BY CARCINOMA

- FOCAL LYMPHVASCULAR SPACE INVASION IS IDENTIFIED

POSTERIOR CUL-DE-SAC, BIOPSY

- INVASIVE SQUAMOUS CELL CARCINOMA

OVARY, RIGHT, BIOPSY

- NO CARCINOMA IDENTIFIED (SEE COMMENT)

LEFT ADNEXA, BIOPSY

- NO CARCINOMA IDENTIFIED (SEE COMMENT)

ICD-O-3

Carcinoma, squamous cell keratinizing NOS
8671/3

Site: Cervix NOS
C53.9

9/21/14

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

M.D.

***Report Electronically Reviewed and Signed Out By

M.D.***

Microscopic Description and Comment:

The cervical cone biopsy contains extensive, invasive, focally keratinizing, moderately differentiated squamous cell carcinoma involving all eight blocks of tissue. The tumor extensively involves one lateral margin and the deep margin. The tumor measures 1.4 cm in greatest lateral dimension and 0.9 cm in depth, as measured from histologic sections.

[page 2 of 2]
however, the tumor may be larger than this given that the resection margins are positive. Lymphovascular space invasion is identified. The surface epithelium adjacent to invasive cancer shows severe dysplasia (CIN 3). The specimen labeled posterior cul-de-sac biopsy contains a very small fragment of invasive squamous cell carcinoma. The endocervical curettage specimen also contains fragments of invasive squamous cell carcinoma.

Histologic sections from the right ovarian biopsy show two fragments of tissue. One contains what appears to be ovarian cortex but which lacks any follicles. A small amount of smooth muscle is present as well as some apparent ovarian surface epithelium. This may represent a portion of cortex adhered to adnexal soft tissue. The other fragment shows fibrous connective tissue with benign appearing squamous epithelium. I cannot confirm that this piece of tissue originates from the ovary. The specimen labeled "left adnexal biopsy" is composed of inflamed connective tissue with smooth muscle and serosal. No definitive ovarian tissue or follicle formation is present. No malignancy is identified in either of these ovarian specimens.

[REDACTED] M.D.

History:

The patient is a [REDACTED] year old woman with pain and bleeding.

Materials Received:

Received are 20 slides labeled [REDACTED] and sublabeled A-L1 to A-L3, B-L1 to B-L3, C-L1 to C-L3; D-L1 to D-L3, and E1 to E8. These are derived from an endocervical curettage (A), a right ovarian biopsy (B), a left adnexal biopsy (C), a posterior cul-de-sac biopsy (D), and a cervical cone biopsy (E) performed [REDACTED]

Physician Copy [REDACTED]
END OF REPORT

Page 2 of 2

Reviewer Initials: [REDACTED] Date Reviewed: 12/15/13		

Source: NCI Genomic Data Commons file 28e7b6b6-f278-4329-abca-9261342d3be5 (TCGA-C5-A8ZZ.38E42051-6D04-4C54-BA9A-8206CC0AFBCB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).